HCMI case HCM-BROD-0121-C41 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Miscellaneous Bone Tumors; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1da2dae2-d5ed-49c9-9f9e-c12e6e262dc4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2000; Vital status: Dead; Days to death: 365 days (1.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; ICD-10 code: C78.2; Tissue or organ of origin: Bone, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 14.2 years (5,196 days); Metastasis at diagnosis: Distant Metastasis; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Lung, NOS / Bone, NOS.
   Pathology details: Tumor largest dimension diameter: 8 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Ifosfamide + Vincristine; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: VDC/IE; Days to treatment start: 0 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Neoadjuvant; Days to treatment start: 334 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan + Temozolomide + Vincristine; Treatment intent type: Neoadjuvant; Regimen or line of therapy: VIT; Days to treatment start: 334 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Neoadjuvant; Days to treatment start: 334 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 334 days; Days to treatment end: 365 days (1.0 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 0 days.
- Days to follow up: 334 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 334 days.
- Days to follow up: 365 days (1.0 years); Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- CD99 (IHC): Positive.
- Test: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 20.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0121-C41-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0121-C41-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 8.
